Surgical pathology report (de-identified scan), TCGA case TCGA-S7-A7WP, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University Hospital Motol, specimen TCGA-S7-A7WP-01A (Primary Tumor).

Gross:

Fibrously encapsulated left adrenal tumor weighing 42 g, 50x45x35 mm. On cut, tumor with soft consistency and pink-red color.

Micro:

Solidly and alveolarly shaped pheochromocytoma with focal hemorrhages. Adrenal cortex outside the tumor with extensive hypolipoidosis, in the surrounding adipose tissue advances Feyrter's metaplasia.

Immunohistochemic staining for S100 protein shows frequent sustentacular cells.

PASS:

Large nests or diffuse growth (>10% of tumor volume)

Central (middle of large nests) or confluent tumor necrosis 2

High cellularity

Cellular monotony

Tumor cell spindling (even if focal)

Mitotic figures >3/10 HPF

Atypical mitotic figure(s)

Extension into adipose tissue

Vascular invasion

Capsular invasion

Profound nuclear pleomorphism 1

Nuclear hyperchromasia 1

Total 2

Procurement date:

Confirmation date:

Pheochromocytoma NOS
870010
Site Adrenal gland NOS
Q74.9
JA 10/9/13

Source: NCI Genomic Data Commons file 7415c434-6e77-486b-8acd-e9a0efc9174b (TCGA-S7-A7WP.69BFE984-4578-4600-AEFE-0BAA1A0A48B2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).